Gene-level copy-number profile of tumor specimen TCGA-AY-6196-01A from TCGA case TCGA-AY-6196, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 47.4 years (17,311 days).
Specimen TCGA-AY-6196-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.7e2d7159-d53e-41d6-ba9d-b6e8168d76c6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AY-6196-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a6e13f7-b128-4c9a-91df-a1f49a218bb0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,927; copy number 2: 22,660; copy number 3: 19,530; copy number 4: 9,776; copy number 5: 3,177; copy number 6: 2,086; copy number 7: 520; copy number 8: 56; copy number 9: 9; copy number 12: 39; copy number 23: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AY-6196-01A-11D-1717-01): tumor purity 0.38, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,762 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,759,170–175,743,616, 402 genes, copy number 6 (broad region; genes not listed).
- chr1:177,170,958–181,061,938, 78 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:183,023,420–189,133,292, 91 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr1:224,030,704–226,446,292, 59 genes, copy number 5: AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, AL391811.1, DNAH14, LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1, LIN9, YBX1P9, AL359742.1, PARP1, AL359704.1, RPS3AP7, RN7SKP165.
- chr1:227,696,892–248,919,946, 530 genes, copy number 5–6 (broad region; genes not listed).
- chr2:52,297,995–62,262,671, 149 genes, copy number 5 (broad region; genes not listed).
- chr2:166,403,573–174,546,335, 124 genes, copy number 5 (broad region; genes not listed).
- chr2:174,557,966–174,558,072, 1 gene, copy number 5: RNU6-5P.
- chr3:78,038,705–87,793,629, 62 genes, copy number 6–9 (broad region; genes not listed).
- chr3:101,521,891–104,503,266, 31 genes, copy number 7–12: FAM172BP, TRMT10C, PCNP, AC073861.1, AC084198.1, RNU6-1256P, Y_RNA, Y_RNA, ZBTB11, RNY1P12, ZBTB11-AS1, RPL24, AC084198.2, PDCL3P4, CEP97, NXPE3, AC020651.1, NFKBIZ, AC020651.2, LINC02085, Y_RNA, AC106712.1, ZPLD1, AC063938.1, RNU6-461P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1.
- chr3:137,518,134–139,006,268, 31 genes, copy number 5: RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A.
- chr3:139,019,031–139,020,926, 1 gene, copy number 5: PRR23B.
- chr4:170,742,469–171,298,267, 9 genes, copy number 5: LINC02382, AC097486.1, RNU6ATAC13P, AC034159.2, LINC02431, AC034159.1, AC092639.1, MIR6082, LINC02504.
- chr5:58,198–44,066,731, 695 genes, copy number 5–7 (broad region; genes not listed).
- chr6:167,607–17,293,871, 306 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr6:45,880,827–48,214,794, 38 genes, copy number 5: CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr6:125,119,049–133,532,128, 124 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:9,614,978–14,071,380, 45 genes, copy number 5: GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21.
- chr7:14,190,795–14,192,157, 1 gene, copy number 5: EEF1A1P26.
- chr8:94,352,923–131,040,909, 531 genes, copy number 5 (broad region; genes not listed).
- chr9:124,481,236–125,438,509, 29 genes, copy number 6 (within-gene range 4–6): NR5A1, AL354979.1, NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2, AL354928.1, OLFML2A, WDR38, RPL35, ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2, PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1, Metazoa_SRP, AL359632.1.
- chr9:135,204,722–138,203,325, 156 genes, copy number 7 (broad region; genes not listed).
- chr12:31,382,226–31,959,316, 25 genes, copy number 5 (within-gene range 3–5): DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1.
- chr13:109,269,634–110,870,251, 31 genes, copy number 5: AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT.
- chr14:32,879,246–32,882,830, 1 gene, copy number 5: AL049781.1.
- chr15:19,878,555–34,850,395, 521 genes, copy number 5 (broad region; genes not listed).
- chr18:12,658,043–13,216,367, 16 genes, copy number 6: PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1.
- chr18:13,234,945–13,236,470, 1 gene, copy number 6: AP002505.1.
- chr18:27,335,968–27,595,164, 1 gene, copy number 6 (within-gene range 4–6): AC090403.1.
- chr18:27,418,884–80,247,514, 733 genes, copy number 6 (broad region; genes not listed).
- chr19:34,396,315–40,796,943, 353 genes, copy number 5–23 (within-gene range 2–23) (broad region; genes not listed).
- chr20:24,237,255–24,680,991, 6 genes, copy number 6: RNU1-23P, AL158090.1, GAPDHP53, SYNDIG1, AL157413.1, AL049594.1.
- chr20:41,331,123–64,313,132, 581 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,890. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
